Somatic mutation profile of tumor specimen 0DWBGB from CCDI case PBCNUZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Appendix; Age at diagnosis: 16.5 years (6,025 days).
Specimen 0DWBGB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bab9713-c147-4107-8eca-a937ba1148d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWBGN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9943d69a-a719-422a-8902-93c22b8a9a02

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 3, Splice Site 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLA2G4A | c.919-1G>A p.X307_splice | Splice Site (SNP) | VAF 43/395 reads (11%) | catalogued as rs1278794297, COSV99054959; called by muse, mutect2
- BLNK | c.1038G>A p.W346* | Nonsense Mutation (SNP) | VAF 89/656 reads (14%) | called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 34/819 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CDC14C | c.547A>G p.K183E (on ENST00000428251; = p.K76E on NM_152627.3) | Missense Mutation (SNP) | VAF 115/718 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MTF1 | c.833_835del p.T278_H279delinsN | In Frame Del (DEL) | VAF 93/724 reads (13%) | called by mutect2, varscan2
- MTF1 | c.647+2T>A p.X216_splice | Splice Site (SNP) | VAF 38/220 reads (17%) | called by mutect2, varscan2
- SMG5 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 91/614 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
